Somatic mutation profile of tumor specimen TCGA-DB-A64S-01A (aliquot TCGA-DB-A64S-01A-11D-A29Q-08) from TCGA case TCGA-DB-A64S, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 20.2 years (7,389 days).
Specimen TCGA-DB-A64S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0dd81d7-ecaa-46e1-8fc5-86541de8c7db.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DB-A64S-10A (Blood Derived Normal), aliquot TCGA-DB-A64S-10A-01D-A29Q-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cfb03de9-3eac-4724-9bff-a9b3a9c12bc7

The open-access MAF lists 11 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Nonsense Mutation 3, Intron 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 18/53 reads (34%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.581T>G p.L194R | Missense Mutation (SNP) | VAF 17/43 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519998, COSV52663681, COSV52677924, COSV52679257, COSV52713187; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ATRX | c.5016G>A p.W1672* | Nonsense Mutation (SNP) | VAF 63/123 reads (51%) | catalogued as COSV64881477; called by muse, mutect2, varscan2
- ATRX | c.874C>T p.Q292* | Nonsense Mutation (SNP) | VAF 7/39 reads (18%) | catalogued as COSV64875650; called by muse, varscan2
- EMCN | c.781A>G p.N261D | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56462662; called by muse, mutect2, varscan2
- FAM47A | c.1616G>A p.R539Q | Missense Mutation (SNP) | VAF 36/46 reads (78%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.776); catalogued as COSV60499122; called by muse, varscan2
- HCN1 | c.2653C>T p.R885* | Nonsense Mutation (SNP) | VAF 44/111 reads (40%) | catalogued as rs1335989876, COSV57501102; called by muse, mutect2, varscan2
- RIMBP2 | c.2092G>A p.A698T | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs748564788, COSV55479187; called by muse, mutect2, varscan2
- ATRX | c.858_866del p.N286_Q289delinsK | In Frame Del (DEL) | VAF 8/50 reads (16%) | called by pindel, varscan2
- KMT2E | c.1458_1477del p.T487Kfs*21 | Frame Shift Del (DEL) | VAF 19/100 reads (19%) | called by mutect2, pindel, varscan2
- DST | c.4297-4335C>G | Intron (SNP) | VAF 46/138 reads (33%) | catalogued as COSV99754888; called by muse, mutect2, varscan2
